Surgical pathology report (de-identified scan), TCGA case TCGA-85-A50Z, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A50Z-01A (Primary Tumor).

1CD-0-3

Carcinoma, squamous cell. NOS 8070/3

Site: lung, upper lobe c34.1

hw
11/8/12

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 6.5 x 5.5 x 5.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/6 positive for metastasis (0/6)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Right- upper

Diagnostic Discrepancy		
Histologic Discrepancy		X
Primary Malignancy History		X
Early Symptomatic Primary Malignancy		

Source: NCI Genomic Data Commons file 944da870-7c93-420f-b142-9da73a0c9d45 (TCGA-85-A50Z.3C1DB929-A01C-4274-B5A9-542237FEA832.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).